Somatic mutation profile of tumor specimen TARGET-20-PARNIN-03A (aliquot TARGET-20-PARNIN-03A-01D) from TARGET case TARGET-20-PARNIN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (413 days).
Specimen TARGET-20-PARNIN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f714ac3e-35c4-422e-a1b9-9d17d99157bb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNIN-14A (Bone Marrow Normal), aliquot TARGET-20-PARNIN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c879482b-cb03-46f9-83c1-c30c26991af5

The open-access MAF lists 25 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 10, Missense Mutation 6, Silent 6, 3'Flank 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2761G>A p.V921M | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs398123650, COSV52424508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSPG4 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1038394539; called by muse, varscan2
- MET | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs201154533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPOR1 | c.2371G>A p.D791N (on ENST00000379312 / NM_001193522.2; = p.D787N on NM_024519.4) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1027466391; called by muse, mutect2, varscan2
- TPR | c.3590T>C p.L1197S | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1367774375; called by muse, mutect2, varscan2
- SRCAP | c.2782C>G p.L928V | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- AHNAK | c.15522C>T p.N5174= | Silent (SNP) | VAF 108/209 reads (52%) | catalogued as rs1450163649; called by muse, mutect2, varscan2
- COL1A1 | c.1812T>C p.P604= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs151328660, CD1110800; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.5101T>C p.L1701= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as rs75467626; called by muse, mutect2, varscan2
- KMT2E | c.3198C>T p.S1066= | Silent (SNP) | VAF 119/216 reads (55%) | catalogued as rs377719958, CD124623; called by muse, mutect2, varscan2
- SPEG | c.3330G>A p.L1110= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs910156964; called by muse, mutect2, varscan2
- TDRD6 | c.3298T>C p.L1100= | Silent (SNP) | VAF 163/344 reads (47%) | called by muse, mutect2, varscan2
- ADCY5 | c.*555del | 3'UTR (DEL) | VAF 43/120 reads (36%) | catalogued as rs948488771; called by mutect2, pindel, varscan2
- ARID1B | chr6:157210238 T>C | 3'Flank (SNP) | VAF 102/214 reads (48%) | catalogued as rs1021637108; called by muse, mutect2, varscan2
- ATF3 | c.348+12C>A | Intron (SNP) | VAF 51/117 reads (44%) | catalogued as rs953930630; called by muse, mutect2, varscan2
- ATXN1 | c.*3780G>A | 3'UTR (SNP) | VAF 70/127 reads (55%) | catalogued as rs888008321; called by muse, mutect2, varscan2
- AXIN1 | c.*575_*625delinsGCCAGCAGGGGCTGCCCGAGTCTGTTTTTCATGCGATGACACTTGTAC | 3'UTR (DEL) | VAF 17/125 reads (14%) | called by pindel, varscan2*
- CBFA2T2 | c.*3701G>T | 3'UTR (SNP) | VAF 120/243 reads (49%) | catalogued as rs892819402; called by muse, mutect2, varscan2
- DICER1 | c.*1894C>T | 3'UTR (SNP) | VAF 79/129 reads (61%) | catalogued as rs540809100; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM5A | c.*4288G>A | 3'UTR (SNP) | VAF 82/177 reads (46%) | catalogued as rs995895054; called by muse, mutect2, varscan2
- MLLT1 | c.*1757G>A | 3'UTR (SNP) | VAF 69/133 reads (52%) | catalogued as rs866572244; called by muse, mutect2, varscan2
- NALCN | c.*1282_*1330delinsTTATAATCTATTTTTCTCTATTTAACATTCCTCAGATAGATAGGCAAAT | 3'UTR (ONP) | VAF 34/144 reads (24%) | called by pindel, varscan2*
- PPP1R15B | c.*1197A>G | 3'UTR (SNP) | VAF 100/221 reads (45%) | catalogued as rs1345969416; called by muse, varscan2
- PTPRT | c.*4145_*4168delinsATGTGCTCTGTTCCTCATGT | 3'UTR (DEL) | VAF 68/235 reads (29%) | called by pindel, varscan2*
- SIN3A | chr15:75369894 A>G | 3'Flank (SNP) | VAF 119/235 reads (51%) | catalogued as rs968010235; called by muse, mutect2, varscan2
